Somatic mutation profile of tumor specimen ALCH-B4VK-TTP1-A (aliquot ALCH-B4VK-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4VK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,579 days).
Specimen ALCH-B4VK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24d61447-10e8-4912-ac0f-d6fb3cfe6fdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4VK-NB1-A (Blood Derived Normal), aliquot ALCH-B4VK-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29364f86-cac5-4e2a-a1ed-702bcad07055

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Nonsense Mutation 2, Intron 2, 3'UTR 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 22/276 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADGRD2 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1184523511; called by muse, mutect2, varscan2
- AUTS2 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1437864529, COSV61387629; called by muse, mutect2, varscan2
- CCDC105 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52965237; called by muse, mutect2, varscan2
- CRACR2A | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs924786719, COSV61543403; called by muse, mutect2
- DLL3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs781119337, COSV99218788; called by muse, mutect2
- EGFR | c.2284-6C>G | Splice Region (SNP) | VAF 41/102 reads (40%) | catalogued as COSV51829805; called by muse, mutect2, varscan2
- LRP1B | c.8131C>T p.R2711C | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs995737118, COSV67218188; called by muse, mutect2, varscan2
- OGDHL | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757281565, COSV65101260; called by muse, mutect2, varscan2
- OR5H1 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756221014; called by muse, mutect2, varscan2
- RAB11FIP5 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.253); catalogued as COSV50248264; called by muse, mutect2, varscan2
- RIMS2 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1421709669, COSV51652319, COSV51695388; called by muse, mutect2
- RPS6KA6 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425343; called by muse, mutect2, varscan2
- ALPK3 | c.4042A>C p.I1348L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FAM162A | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- IL22 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LAMC2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NBR1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ODF2 | c.1460G>A p.R487Q (on ENST00000434106 / NM_153433.2; = p.R463Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OTOF | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PI4KA | c.2381T>G p.L794R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLAAT4 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PLEKHA3 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- RPL10A | c.4A>T p.S2C | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- RWDD2B | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.536_537insA p.W180Lfs*91 | Frame Shift Ins (INS) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- TRAF3 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- UBA1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UFL1 | c.629A>C p.Y210S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- VEZT | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AP3S1 | c.210G>A p.T70= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as rs766399528, COSV100372658; called by muse, mutect2
- CNN2 | c.135C>T p.S45= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- GPRC5A | c.705C>T p.D235= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- GRIPAP1 | c.2425T>C p.L809= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- LRRC9 | c.3462C>T p.I1154= | Silent (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- OR13H1 | c.732G>C p.L244= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- PPP1R9A | c.372T>C p.I124= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- PGAP1 | c.1619+60T>G | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- TTC1 | c.*264G>A | 3'UTR (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5472G>T | RNA (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- ZNF397 | c.556+43C>T | Intron (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
